Surgical pathology report (de-identified scan), TCGA case TCGA-68-8251, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - Cleveland Clinic, specimen TCGA-68-8251-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

De-Identified Specimen Code: [REDACTED]

Patient Age/Sex [REDACTED]

SPECIMEN SUBMITTED:

Part A: LEFT UPPER LOBE

Part B: LEVEL 11

Part C: LEVEL 10

Part D: AP WINDOW LYMPH NODE

Final Diagnosis

1. Left lung, upper lobe, lobectomy (A) - Invasive poorly differentiated squamous cell carcinoma.
- Four (4) peribronchiolar lymph nodes, negative for neoplasm.
- Centrilobular emphysema.
2. Lymph nodes 11, 10, AP window, excision (B-D) - Lymph nodes, negative for neoplasm.

Diagnosis Comment:

Tumor Location: Left upper lobe

Tumor Size: 4.2 x 3.5 x 3.0 cm

Vascular Invasion: Absent.

Lymphatic Invasion: Absent

Bronchial Margin: Negative

Vascular Margin: Negative

Parenchymal Margins: Negative

Pleura/Soft Tissue Margin: The visceral pleura is negative for neoplasm.

Pathologic Stage (AJCC): pT2a N0 (Stage IB)

General comment: A p63 immunohistochemical stain shows diffuse strong positivity. A TTF-1 immunohistochemical stain is negative. Overall, these findings support the above diagnosis.

Intraoperative Diagnosis:

- A. Negative for neoplasm.

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Clinical Diagnosis:

LUNG CA

Gross Description:

A. Received fresh at the frozen desk is a specimen labeled "left upper lobe". It consists of a 357 gram lobectomy specimen of the left upper lobe measuring 24.0 x 9.5 x 3.5 cm. The bronchial remnant is approximately 0.3 cm in length. In the central segment, there is a poorly circumscribed firm gray-white tumor measuring 4.2 x 3.5 x 3.0 cm with scattered necrosis and hemorrhage that is 2.5 cm from bronchial margin. The tumor causes retraction of the overlying pleura, but does not grossly invade through the pleura, which has a smooth, glistening surface. The tumor grossly invades an adjacent bronchus. The tumor grossly surrounds large vessels. The remainder of the lung is unremarkable. There are four anthracotic hilar lymph nodes, the largest measuring 1.2 cm in greatest dimension. Representative sections are submitted as follows: A1-A2 bronchial margin for frozen section, A3 vessel margins, A4-A5 mass with pleura, A6 bronchial involvement by mass, A7 vessels surrounded by mass, A8 representative section of mass, A9 uninvolved parenchyma, A10 one possible lymph node, A11 three possible lymph nodes.

B. Received fresh labeled "level 11" are multiple irregular shaped segments of red-gray soft tissue aggregating to 1.0 x 0.6 x 0.3 cm. The specimen is totally submitted in formalin in one cassette.

C. Received fresh labeled "level 10" are multiple irregular shaped segments of red-gray soft tissue aggregating to 0.9 x 0.7 x 0.3 cm. The specimen is totally submitted in formalin in one cassette.

D. Received fresh labeled "AP window lymph node" are multiple irregular shaped segments of red-gray soft tissue aggregating to 2.1 x 1.5 x 0.7 cm. The specimen is totally submitted in formalin in one cassette.

Microscopic:

{Not Entered}

Source: NCI Genomic Data Commons file b8296de1-5301-47d9-8649-bf7e44407d1f (TCGA-68-8251.CA919E01-66E2-4307-B0EF-2DDA4C1CA840.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).